Somatic mutation profile of tumor specimen TCGA-AY-5543-01A (aliquot TCGA-AY-5543-01A-01D-1650-10) from TCGA case TCGA-AY-5543, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 65.4 years (23,870 days).
Specimen TCGA-AY-5543-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 797f31c6-5f99-4420-bad0-9b6943923c35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-5543-10A (Blood Derived Normal), aliquot TCGA-AY-5543-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cf79a42-860d-4498-8fb1-df0a20b2bcaa

The open-access MAF lists 122 somatic variants for this specimen: 87 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 34, Nonsense Mutation 3, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 119/340 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 88/158 reads (56%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs374668733; called by muse, mutect2, varscan2
- ADAMTS13 | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs782621505, COSV52470785, COSV52471128; called by muse, mutect2, varscan2
- ANKS1A | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.084); catalogued as rs1003982394, COSV64463007; called by muse, mutect2, varscan2
- APC | c.4476del p.T1493Rfs*14 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | catalogued as COSV57375363; called by mutect2, pindel, varscan2
- ATP10B | c.3779G>A p.G1260D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as rs752822985, COSV59160597; called by muse, mutect2, varscan2
- BMPER | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51827033; called by muse, mutect2, varscan2
- CCDC137 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs371084134, COSV61303696; called by muse, mutect2, varscan2
- CCDC170 | c.1053G>T p.K351N | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV53344143; called by muse, mutect2, varscan2
- CD109 | c.2989C>A p.L997I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV54648923, COSV54654051; called by muse, mutect2, varscan2
- CHST10 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1389279650, COSV51806871; called by muse, mutect2, varscan2
- CMTR1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1248821263, COSV65091162; called by muse, mutect2, varscan2
- CNBD1 | c.297A>C p.E99D | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV72917341; called by muse, mutect2, varscan2
- COL22A1 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57350964; called by muse, mutect2, varscan2
- COL5A2 | c.1373C>G p.T458S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.956); catalogued as rs863223489, COSV66412625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A2 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs754945201, COSV101028366; called by muse, mutect2, varscan2
- CSMD1 | c.10541C>T p.T3514M (on ENST00000520002; = p.T3513M on NM_033225.6) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs564031277, COSV59358109; called by muse, mutect2, varscan2
- CYP27C1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761337472, COSV58867602; called by muse, mutect2, varscan2
- DBNDD1 | c.433G>C p.V145L (on ENST00000002501 / NM_001042610.3; = p.V165L on NM_024043.3) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV50022446; called by muse, mutect2, varscan2
- DDX60L | c.3989A>C p.K1330T | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52718816; called by muse, mutect2, varscan2
- DGKB | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51806309; called by muse, mutect2, varscan2
- DIP2B | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1439939886, COSV56589002; called by muse, mutect2, varscan2
- DIS3 | c.963G>T p.E321D | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100899822; called by muse, mutect2, varscan2
- DMRTC2 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99523287; called by muse, mutect2
- DSCAML1 | c.3392G>A p.R1131Q (on ENST00000321322; = p.R1071Q on NM_020693.4) | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs753409238, COSV100354471; called by muse, mutect2, varscan2
- EFNB1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52662392; called by muse, mutect2, varscan2
- FREM2 | c.3598G>A p.V1200M | Missense Mutation (SNP) | VAF 181/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748241053, COSV54846044; called by muse, mutect2, varscan2
- GABRQ | c.632T>A p.I211N | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64783344; called by muse, mutect2, varscan2
- IGHE | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370977516; called by muse, mutect2, varscan2
- ITIH6 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV54492275; called by muse, mutect2, varscan2
- ITPRID2 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100237829; called by muse, mutect2, varscan2
- KCNV1 | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV52087870; called by muse, mutect2, varscan2
- KIF24 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100799097; called by muse, mutect2, varscan2
- KRTAP6-3 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 108/341 reads (32%) | PolyPhen probably damaging (0.999); catalogued as COSV66963240; called by muse, mutect2, varscan2
- LARP1 | c.2867G>A p.R956Q (on ENST00000518297 / NM_033551.3; = p.R879Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 251/526 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60429898; called by muse, mutect2, varscan2
- MAP6 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as rs573813818, COSV59077004; called by muse, mutect2, varscan2
- MED12L | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779087284, COSV56371208; called by muse, mutect2, varscan2
- MERTK | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54933229; called by muse, mutect2, varscan2
- MGAM | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs374712168; called by muse, mutect2
- MIDEAS | c.106dup p.Q36Pfs*33 | Frame Shift Ins (INS) | VAF 28/51 reads (55%) | catalogued as rs760940567; called by mutect2, varscan2
- MPDZ | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59949269; called by muse, mutect2, varscan2
- MXRA5 | c.8047C>A p.Q2683K | Missense Mutation (SNP) | VAF 114/336 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54244048; called by muse, mutect2, varscan2
- NCKAP5L | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100258653, COSV60131682; called by muse, mutect2, varscan2
- NEDD4L | c.2684G>A p.R895H (on ENST00000400345 / NM_001144967.3; = p.R875H on NM_015277.6) | Missense Mutation (SNP) | VAF 86/143 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56847155; called by muse, mutect2, varscan2
- NRDC | c.2932G>T p.A978S | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV61406984; called by muse, mutect2, varscan2
- OR51D1 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100712341, COSV62914005; called by muse, mutect2, varscan2
- OTUD6A | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100610921; called by muse, mutect2, varscan2
- PAK4 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58946148; called by muse, mutect2, varscan2
- PARP9 | c.186G>C p.W62C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV64451419; called by muse, mutect2, varscan2
- PCDHB8 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 170/543 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as rs781811938, COSV50806831; called by muse, varscan2
- PDYN | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201655505, COSV54102842; called by muse, mutect2, varscan2
- PHIP | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753204166; called by muse, mutect2, varscan2
- PRKACG | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55254016; called by muse, mutect2, varscan2
- PRKAG1 | c.314A>C p.Q105P | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV60293867; called by muse, mutect2, varscan2
- PRKCB | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100332094; called by muse, mutect2, varscan2
- SCN5A | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs41313667, CM157157, COSV61126581; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- SDK1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV67379743; called by muse, mutect2, varscan2
- SDK1 | c.3616C>A p.P1206T | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67368040, COSV67381763; called by muse, mutect2, varscan2
- SGCD | c.177G>T p.M59I (on ENST00000435422 / NM_001128209.2; = p.M60I on NM_000337.5) | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100548576; called by muse, mutect2, varscan2
- SGO1 | c.1465C>T p.L489F (on ENST00000263753 / NM_001012410.5; = p.L220F on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99768117; called by muse, varscan2
- SKAP1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs573034197, COSV61143949; called by muse, mutect2, varscan2
- SMC2 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV53962391; called by muse, mutect2
- SMPD2 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99237722; called by muse, mutect2, varscan2
- SPHKAP | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100764671, COSV60884086, COSV60889278; called by muse, mutect2, varscan2
- SRCAP | c.3211C>G p.L1071V | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52677894; called by muse, mutect2
- SRPK1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as COSV60414816; called by muse, mutect2, varscan2
- SYN1 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.662); catalogued as COSV55983731; called by muse, mutect2, varscan2
- TADA3 | c.1197G>A p.M399I | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs896549764, COSV57334034; called by muse, mutect2, varscan2
- TENT4B | c.905C>T p.S302L (on ENST00000561678 / NM_001365323.2; = p.S287L on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV62548677; called by muse, mutect2, varscan2
- TNN | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV53431923; called by muse, mutect2, varscan2
- TOPORS | c.1528A>G p.M510V | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV62117773; called by muse, mutect2, varscan2
- TSHZ3 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs749560411, COSV53678144; called by muse, mutect2, varscan2
- TSPOAP1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as rs750610515, COSV52107146; called by muse, mutect2, varscan2
- UNC80 | c.101T>G p.L34W | Missense Mutation (SNP) | VAF 185/529 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55900389; called by muse, mutect2, varscan2
- USH2A | c.5948T>A p.V1983E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100228529; called by muse, mutect2, varscan2
- VCAN | c.9361G>A p.G3121R | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314929549, COSV54108796, COSV99424537; called by muse, mutect2, varscan2
- VPS13B | c.7387G>A p.A2463T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62132706; called by muse, mutect2
- VWCE | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs199639781, COSV57114059; called by muse, mutect2, varscan2
- ZFHX4 | c.9001G>A p.G3001R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs772582651, COSV50490189; called by muse, mutect2, varscan2
- ZNF45 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs769073477, COSV54194121; called by muse, mutect2, varscan2
- ZNF695 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 49/132 reads (37%) | catalogued as COSV60586986; called by muse, mutect2, varscan2
- ZSCAN20 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV63683898; called by muse, mutect2, varscan2
- ACACA | c.6418C>T p.R2140W | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MAP2K4 | c.745_750del p.G249_I250del | In Frame Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- ABHD4 | c.669G>A p.P223= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as rs766894580, COSV53530063; called by muse, mutect2, varscan2
- ADGRG5 | c.1269G>A p.T423= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs140347967; called by muse, mutect2, varscan2
- AJAP1 | c.594G>A p.P198= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs370401960, COSV100981982; called by muse, mutect2, varscan2
- ATRIP | c.891T>C p.F297= | Silent (SNP) | VAF 67/238 reads (28%) | catalogued as COSV57178089; called by muse, mutect2
- BTRC | c.810A>C p.A270= (on ENST00000370187 / NM_033637.4; = p.A234= on NM_003939.5) | Silent (SNP) | VAF 104/335 reads (31%) | catalogued as COSV64580368; called by muse, mutect2, varscan2
- CAMK2A | c.702G>A p.S234= | Silent (SNP) | VAF 138/450 reads (31%) | catalogued as rs371411676; called by muse, mutect2, varscan2
- CC2D2B | c.282T>A p.L94= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV60358726; called by muse, mutect2, varscan2
- CHD5 | c.4563C>T p.N1521= | Silent (SNP) | VAF 86/252 reads (34%) | catalogued as rs1372254803, COSV52421229; called by muse, mutect2, varscan2
- COL27A1 | c.4383C>T p.D1461= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs1199082188, COSV61929280; called by muse, mutect2, varscan2
- COL5A1 | c.4239C>T p.A1413= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs537406193, COSV65665263; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTSF | c.1005C>T p.G335= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs147269500; called by muse, mutect2, varscan2
- EMC1 | c.2412G>A p.E804= | Silent (SNP) | VAF 77/200 reads (39%) | catalogued as COSV64346297; called by muse, mutect2, varscan2
- GUCY2D | c.1623C>T p.S541= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs760501583, COSV54697115; called by muse, mutect2, varscan2
- KCNA4 | c.1344G>T p.L448= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs780340601, COSV60254759; called by muse, mutect2, varscan2
- KIF2B | c.1161C>T p.V387= | Silent (SNP) | VAF 120/362 reads (33%) | catalogued as rs747769826, COSV52133713; called by muse, mutect2
- LAMC2 | c.1398C>T p.N466= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as rs189665394, COSV51458230; called by muse, mutect2, varscan2
- MECOM | c.3120G>A p.A1040= (on ENST00000468789 / NM_001105078.4; = p.A1228= on NM_004991.4) | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs750090830, COSV52970477; called by muse, mutect2, varscan2
- MID1 | c.1689G>A p.P563= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs765392240, COSV58197537; called by muse, mutect2, varscan2
- OR10J3 | c.726C>T p.C242= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs773890539, COSV59955216, COSV59955893; called by muse, mutect2, varscan2
- OR2T12 | c.516C>A p.I172= | Silent (SNP) | VAF 127/413 reads (31%) | catalogued as COSV58777432, COSV58778756; called by muse, mutect2, varscan2
- PANK2 | c.1503T>A p.I501= (on ENST00000316562 / NM_153638.3; = p.I210= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/215 reads (13%) | catalogued as COSV100262094; called by muse, mutect2, varscan2
- PEBP1 | c.501G>A p.T167= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs146924072; called by muse, mutect2, varscan2
- PELP1 | c.1974G>A p.S658= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs750844787, COSV52590676; called by muse, mutect2, varscan2
- PLA2G4C | c.1593G>A p.P531= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs779631342, COSV53153536; called by muse, mutect2, varscan2
- PRCC | c.291C>T p.S97= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV54857775; called by muse, mutect2, varscan2
- RYR2 | c.12084G>A p.S4028= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs751821960, COSV63682739, COSV63702754; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNE1 | c.19602A>G p.K6534= (on ENST00000367255 / NM_182961.4; = p.K6463= on NM_033071.3) | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV55054236; called by muse, mutect2, varscan2
- TBC1D4 | c.613C>T p.L205= | Silent (SNP) | VAF 74/348 reads (21%) | catalogued as COSV100884516; called by muse, varscan2
- TRAIP | c.384C>T p.A128= | Silent (SNP) | VAF 83/256 reads (32%) | catalogued as rs149686258; called by muse, mutect2, varscan2
- TRIM69 | c.1047C>T p.D349= (on ENST00000329464 / NM_182985.5; = p.D190= on NM_080745.5) | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as rs367675407; called by muse, mutect2, varscan2
- TSR1 | c.1473C>T p.P491= | Silent (SNP) | VAF 80/144 reads (56%) | catalogued as rs200666955, COSV56786303; called by muse, mutect2, varscan2
- UBE3D | c.393G>A p.P131= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs368145943, COSV52752970; called by muse, mutect2, varscan2
- USP47 | c.3684G>A p.L1228= (on ENST00000399455 / NM_001372095.1; = p.L1140= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV59694453; called by muse, mutect2, varscan2
- ZNF536 | c.2346G>A p.P782= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs769979658, COSV62830339; called by muse, mutect2, varscan2
- ZDHHC11 | c.*2A>G | 3'UTR (SNP) | VAF 69/511 reads (14%) | catalogued as COSV99362170; called by muse, varscan2
